Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5794, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5794-01A (Primary Tumor).

Diagnosis

1. Poorly differentiated, max. 1.3 cm, acinar adenocarcinoma of the prostate in both lobes with perineural growth also along major nerves, limited to the prostate, and with tumor-free seminal vesicles and seminal ducts.
2. Tumor-free fatty connective tissue with vessels and nerves. No malignancy.
3. Six tumor-free lipomatous lymph nodes. No malignancy.
4. Four tumor-free lipomatous lymph nodes.

Remark

Carcinoma infiltrates are found in the peripheral zone with left and right dorsolateral predominance in the middle portion. On the left side, carcinoma cells extend in sections to within < 0.1 mm of the color-labeled preparation margin, but the green and blue labeled area itself is carcinoma-free. No invasion of the vessels is identifiable.

In summary, the tumor classification is as follows:

pT2c, pN0 (0/4); Gleason 3+4 = 7, approx. 40% Gleason 4, G3, L0, V0.

Source: NCI Genomic Data Commons file 27ca42ea-ac38-4022-b976-1d575c2ff8e8 (TCGA-CH-5794.2BDBD62B-C2A0-4CDD-8187-6CF1DB227E7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).